CPTAC case C3L-01285 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d8ef8a50-9276-4733-a15c-ad0fdc0b2910

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1963; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 54.0 years (19,737 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,697 days (4.6 years); Progression or recurrence: yes; Days to last follow up: 1,697 days (4.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm (a second GDC size field records 4 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 7; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 448 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 1,063 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,420 days (3.9 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 610 days (1.7 years).
- Days to follow up: 1,420 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,697 days (4.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 686.

Other clinical attributes
- Weight: 67 kg; Height: 177 cm; BMI: 21.39.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Cigarettes per day: 0; Tobacco smoking onset year: 1982; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 40.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01285-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 238 mg.
- Sample C3L-01285-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 280 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01285-22: Section location: Left Upper Lobe; Percent tumor nuclei: 65; Percent necrosis: 5.
- Sample C3L-01285-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 298 mg.
- Sample C3L-01285-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 371 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01285-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
